Somatic mutation profile of tumor specimen cf795cd2-317b-4897-a35e-390001 (aliquot cf795cd2-317b-4897-a35e-390001_D6_1) from CPTAC case 11CO021, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA.
Specimen cf795cd2-317b-4897-a35e-390001: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ce34fbd-6c92-45d2-8f08-3fa42c7fb73f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen fa74656d-803c-4984-bbcd-8f3179 (Blood Derived Normal), aliquot fa74656d-803c-4984-bbcd-8f3179_D1_2; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e5471a3-5d20-467e-b00f-19f14cbdcfc3

The open-access MAF lists 131 somatic variants for this specimen: 97 protein-altering or splice-affecting, 23 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 23, Nonsense Mutation 8, Intron 6, Frame Shift Ins 5, Splice Site 5, 3'UTR 2, Frame Shift Del 2, 5'Flank 1, Splice Region 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 196/427 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 168/322 reads (52%) | hotspot (GDC flag); catalogued as rs121912652, CM900213, COSV52684909, COSV52740428, COSV52828352; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.709A>G p.M237V | Missense Mutation (SNP) | VAF 157/303 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730882004, COSV52701833, COSV52875518, COSV53198341; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.9485G>A p.R3162Q | Missense Mutation (SNP) | VAF 75/215 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs369327461; called by muse, mutect2, varscan2
- ACAN | c.7645C>T p.R2549C (on ENST00000560601 / NM_001369268.1; = p.R2412C on NM_001135.3) | Missense Mutation (SNP) | VAF 87/266 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs571382991, COSV61358532; called by muse, mutect2, varscan2
- APC | c.2510C>G p.S837* | Nonsense Mutation (SNP) | VAF 140/417 reads (34%) | catalogued as rs79512956, CD011083, CD084036, CM014886, COSV57338611, COSV57345932; ClinVar: other; called by muse, mutect2, varscan2
- ARFGEF3 | c.4898C>T p.T1633M | Missense Mutation (SNP) | VAF 71/136 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as rs368323145; called by muse, mutect2, varscan2
- C5orf47 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.057); catalogued as rs987682213; called by muse, mutect2, varscan2
- COL6A1 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.109); catalogued as rs757791812, COSV62611723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A1 | c.2543C>G p.T848S | Missense Mutation (SNP) | VAF 132/507 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.047); catalogued as rs1385874632; called by muse, mutect2, varscan2
- CTNNA2 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63550258; called by muse, mutect2
- ECHDC1 | c.795dup p.S266Ifs*36 (on ENST00000531967 / NM_001139510.1; = p.S260Ifs*36 on NM_001002030.2) | Frame Shift Ins (INS) | VAF 22/222 reads (10%) | catalogued as rs772315663; called by mutect2, pindel, varscan2
- EPHB4 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 202/632 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs774048106, COSV100639524; called by muse, mutect2, varscan2
- F8 | c.3275dup p.N1092Kfs*26 | Frame Shift Ins (INS) | VAF 57/220 reads (26%) | catalogued as rs1168788831; called by mutect2, pindel, varscan2
- FERD3L | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 69/246 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs866406481, COSV51762348; called by muse, mutect2, varscan2
- FGFR1 | c.622-1G>T p.X208_splice (on ENST00000447712 / NM_023110.3; = p.X206_splice on NM_015850.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 176/370 reads (48%) | catalogued as CS158515; called by mutect2, varscan2
- GABRG2 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 37/342 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62723536; called by mutect2, varscan2
- GPR26 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs1405244525, COSV52936549; called by muse, mutect2, varscan2
- IGHV3-13 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 140/337 reads (42%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.006); catalogued as rs111423442; called by muse, mutect2, varscan2
- IL4R | c.2418C>G p.S806R | Missense Mutation (SNP) | VAF 69/216 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as rs1195332596; called by muse, mutect2, varscan2
- IQSEC2 | c.884G>A p.R295Q (on ENST00000642864 / NM_001111125.3; = p.R90Q on NM_015075.2) | Missense Mutation (SNP) | VAF 111/377 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1569306306; called by muse, mutect2, varscan2
- KCND3 | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 229/480 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56185564; called by muse, mutect2, varscan2
- KIN | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as rs772662628; called by muse, mutect2, varscan2
- LAMA5 | c.11018C>T p.S3673F | Missense Mutation (SNP) | VAF 58/288 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.309); catalogued as rs762967226; called by muse, mutect2, varscan2
- LRRC9 | c.59A>G p.N20S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760898442; called by muse, varscan2
- MAGEA9 | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.107); catalogued as rs1340906701; called by mutect2, varscan2
- OR56A5 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 90/300 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.021); catalogued as rs774047367; called by muse, mutect2, varscan2
- OSTM1 | c.472C>G p.L158V | Missense Mutation (SNP) | VAF 79/126 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as COSV99514137; called by muse, mutect2, varscan2
- PHACTR1 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 58/173 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs1172881850; called by muse, mutect2, varscan2
- PHF24 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 76/264 reads (29%) | catalogued as COSV54273965; called by muse, mutect2, varscan2
- PKD2 | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1308512918, COSV52938429; called by muse, mutect2
- PPFIA1 | c.866C>T p.T289M | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs150126116; called by muse, mutect2, varscan2
- PPP2CB | c.616C>A p.R206S | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as COSV55328990; called by muse, mutect2, varscan2
- SLC25A23 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as rs761364136; called by muse, mutect2, varscan2
- SNRPA1 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs150710048; called by muse, mutect2, varscan2
- SORCS1 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 158/499 reads (32%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.003); catalogued as COSV53855674; called by muse, mutect2, varscan2
- SPATA31A1 | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 103/350 reads (29%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.561); catalogued as rs1279869651; called by muse, mutect2, varscan2
- SUSD1 | c.1462A>G p.T488A | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as rs1393968219; called by muse, mutect2, varscan2
- SYT14 | c.1052A>G p.H351R | Missense Mutation (SNP) | VAF 136/331 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147813274; called by muse, mutect2, varscan2
- TENT4A | c.731T>G p.I244R | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50099493; called by muse, mutect2, varscan2
- TMTC2 | c.1745G>A p.R582Q | Missense Mutation (SNP) | VAF 91/283 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.559); catalogued as rs777976259; called by muse, mutect2, varscan2
- UGT1A1 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 115/364 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750453538, CM051660, CM051661, COSV59394599; called by muse, mutect2, varscan2
- ZNF462 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 109/317 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs769185176; called by muse, mutect2, varscan2
- ZNF729 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | catalogued as rs775219864, COSV62606614; called by muse, mutect2, varscan2
- ABCA13 | c.6521_6522insC p.I2175Yfs*3 | Frame Shift Ins (INS) | VAF 22/81 reads (27%) | called by mutect2, pindel, varscan2
- ABCC10 | c.1252C>A p.Q418K (on ENST00000372530 / NM_001198934.2; = p.Q375K on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/317 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.061); called by muse, mutect2
- ADGRA2 | c.3001G>A p.G1001R | Missense Mutation (SNP) | VAF 54/349 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AP002495.1 | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- APC | c.3852del p.D1285Mfs*3 | Frame Shift Del (DEL) | VAF 81/351 reads (23%) | called by mutect2, pindel, varscan2
- BCORL1 | c.3866G>T p.S1289I | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- CADPS | c.1403G>T p.G468V | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAMK2A | c.362A>G p.E121G | Missense Mutation (SNP) | VAF 83/316 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD1A | c.562T>G p.L188V | Missense Mutation (SNP) | VAF 73/240 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- CDH23 | c.5983T>A p.Y1995N | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0.005); called by muse, mutect2
- CELSR1 | c.7901C>A p.A2634E | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- CFHR3 | c.493T>C p.Y165H | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CPLX2 | c.401A>T p.K134M | Missense Mutation (SNP) | VAF 37/289 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRIM1 | c.2381G>A p.C794Y | Missense Mutation (SNP) | VAF 43/283 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EYS | c.5806C>A p.Q1936K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.671); called by muse, mutect2
- GPR158 | c.1999-4_2037del p.X667_splice | Splice Site (DEL) | VAF 47/268 reads (18%) | called by mutect2, pindel, varscan2
- KAT6B | c.4129A>C p.N1377H | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MAN1B1 | c.328+11_328+25del | Splice Region (DEL) | VAF 115/451 reads (25%) | called by mutect2, pindel, varscan2
- MED12 | c.2553T>A p.N851K | Missense Mutation (SNP) | VAF 50/542 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); called by muse, mutect2
- MGAM2 | c.2468A>G p.D823G | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- MYH14 | c.3056A>G p.K1019R | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- NIPBL | c.793A>G p.R265G | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- NPC1L1 | c.1627_1646del p.M543Cfs*17 | Frame Shift Del (DEL) | VAF 28/260 reads (11%) | called by mutect2, pindel
- NXPE4 | c.659G>A p.G220D | Missense Mutation (SNP) | VAF 137/406 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OR10A5 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 121/373 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR4C11 | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR4D9 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 47/348 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PCDH11X | c.759G>T p.E253D | Missense Mutation (SNP) | VAF 111/337 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PCDHGA9 | c.829G>T p.V277L | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- PIAS3 | c.1859G>A p.C620Y | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.447); called by mutect2, varscan2
- PPA1 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 15/95 reads (16%) | called by muse, mutect2, varscan2
- PPP1R26 | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 72/396 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.046); called by muse, varscan2
- PPP2CB | c.617G>T p.R206L | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPRC | c.3422T>C p.I1141T | Missense Mutation (SNP) | VAF 106/458 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SAGE1 | c.2391C>G p.D797E | Missense Mutation (SNP) | VAF 66/206 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.448); called by muse, varscan2
- SAMD9L | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 14/262 reads (5%) | called by muse, mutect2
- SCUBE3 | c.46G>A p.V16I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SECISBP2L | c.1680dup p.G561Rfs*16 (on ENST00000559471 / NM_001193489.2; = p.G516Rfs*16 on NM_014701.4) | Frame Shift Ins (INS) | VAF 38/154 reads (25%) | called by mutect2, varscan2
- SMURF2 | c.201-2A>G p.X67_splice | Splice Site (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- TDRD1 | c.636-1G>C p.X212_splice | Splice Site (SNP) | VAF 32/144 reads (22%) | called by muse, mutect2, varscan2
- TENM4 | c.692A>T p.E231V | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- THOC1 | c.1838C>G p.A613G | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- TMC4 | c.427C>G p.Q143E (on ENST00000617472 / NM_001145303.3; = p.Q137E on NM_144686.4) | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TMEM232 | c.1179A>T p.K393N | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- TTN | c.4492G>C p.V1498L (on ENST00000591111; = p.V1452L on NM_003319.4) | Missense Mutation (SNP) | VAF 124/433 reads (29%) | PolyPhen benign (0.01); called by muse, mutect2, varscan2
- USH2A | c.4526T>A p.L1509Q | Missense Mutation (SNP) | VAF 193/450 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- VAT1L | c.879dup p.S294Ifs*15 | Frame Shift Ins (INS) | VAF 28/96 reads (29%) | called by mutect2, pindel, varscan2
- XPNPEP1 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 33/111 reads (30%) | called by muse, mutect2, varscan2
- YPEL1 | c.161+1G>A p.X54_splice | Splice Site (SNP) | VAF 58/125 reads (46%) | called by muse, mutect2, varscan2
- ZKSCAN4 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF229 | c.616C>A p.L206I | Missense Mutation (SNP) | VAF 110/321 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ZNF232 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 117/235 reads (50%) | called by muse, mutect2, varscan2
- ZNF845 | c.2068C>A p.P690T | Missense Mutation (SNP) | VAF 91/438 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AADACL2 | c.591G>A p.A197= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as rs772579314; called by muse, mutect2, varscan2
- C12orf71 | c.306C>T p.D102= | Silent (SNP) | VAF 105/546 reads (19%) | called by muse, mutect2, varscan2
- CADPS | c.2481C>G p.T827= | Silent (SNP) | VAF 48/128 reads (38%) | called by muse, mutect2, varscan2
- CASQ1 | c.1113G>A p.E371= | Silent (SNP) | VAF 46/231 reads (20%) | catalogued as rs1475818137; called by muse, mutect2, varscan2
- CFAP69 | c.2475G>A p.T825= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs374396434; called by muse, mutect2
- DENND4B | c.954C>T p.I318= | Silent (SNP) | VAF 278/593 reads (47%) | catalogued as rs767685316; called by muse, mutect2, varscan2
- DOCK3 | c.3153A>G p.L1051= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- DPP6 | c.1515G>A p.T505= (on ENST00000377770 / NM_001364500.2; = p.T443= on NM_001936.5) | Silent (SNP) | VAF 59/211 reads (28%) | catalogued as rs774306342, COSV59613705; called by muse, mutect2, varscan2
- FAT4 | c.828C>T p.D276= | Silent (SNP) | VAF 31/117 reads (26%) | catalogued as COSV101271941; called by muse, mutect2, varscan2
- FBXO46 | c.1275C>T p.A425= | Silent (SNP) | VAF 75/181 reads (41%) | catalogued as rs779731279, COSV100480206; called by muse, mutect2, varscan2
- HAUS5 | c.1254G>A p.P418= | Silent (SNP) | VAF 65/213 reads (31%) | catalogued as rs193073168; called by muse, mutect2, varscan2
- HCN4 | c.174C>G p.P58= | Silent (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- HGF | c.948T>G p.T316= | Silent (SNP) | VAF 82/260 reads (32%) | catalogued as rs770323794, COSV55956167; called by muse, mutect2, varscan2
- NDRG4 | c.645G>T p.R215= (on ENST00000570248 / NM_001378344.1; = p.R247= on NM_020465.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 58/177 reads (33%) | called by muse, mutect2, varscan2
- PLEKHG2 | c.1515C>T p.S505= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs200990352, COSV52681391; called by muse, mutect2, varscan2
- PLG | c.984C>T p.D328= | Silent (SNP) | VAF 128/234 reads (55%) | catalogued as rs780494393, COSV51980360, COSV51984788; called by muse, mutect2, varscan2
- POU4F2 | c.660G>A p.P220= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV55586651; called by muse, mutect2
- RTL9 | c.789G>A p.T263= | Silent (SNP) | VAF 212/585 reads (36%) | catalogued as rs754512240, COSV71825476; called by muse, mutect2, varscan2
- SEMA3B | c.63G>T p.L21= | Silent (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2, varscan2
- TRPC5 | c.2613T>C p.I871= | Silent (SNP) | VAF 80/302 reads (26%) | called by muse, mutect2, varscan2
- VWA8 | c.3702T>C p.F1234= | Silent (SNP) | VAF 16/121 reads (13%) | called by muse, mutect2, varscan2
- ZMPSTE24 | c.393A>G p.T131= | Silent (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- ZXDB | c.732G>A p.A244= | Silent (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- AC104452.1 | c.*67G>T | 3'UTR (SNP) | VAF 151/476 reads (32%) | called by muse, mutect2, varscan2
- CDC6 | c.1453-22G>C | Intron (SNP) | VAF 58/143 reads (41%) | called by muse, mutect2, varscan2
- GSS | c.1301+36C>T | Intron (SNP) | VAF 83/276 reads (30%) | called by muse, mutect2, varscan2
- HAGHL | c.*219G>A | 3'UTR (SNP) | VAF 37/115 reads (32%) | called by muse, mutect2, varscan2
- OSBPL1A | c.626-2889C>T | Intron (SNP) | VAF 16/61 reads (26%) | catalogued as rs1489500700; called by muse, mutect2, varscan2
- PEX19 | c.71-516G>C | Intron (SNP) | VAF 12/208 reads (6%) | called by muse, mutect2
- PIPSL | n.1113C>T | RNA (SNP) | VAF 242/742 reads (33%) | called by muse, mutect2, varscan2
- RNF32 | chr7:156640416 G>T | 5'Flank (SNP) | VAF 34/97 reads (35%) | called by muse, mutect2, varscan2
- SINHCAF | c.-21+737C>T | Intron (SNP) | VAF 30/116 reads (26%) | called by muse, mutect2, varscan2
- TAF9B | c.-3A>G | 5'UTR (SNP) | VAF 9/131 reads (7%) | called by muse, mutect2
- TTN | c.9988+42G>T | Intron (SNP) | VAF 97/332 reads (29%) | called by muse, mutect2, varscan2
